Somatic mutation profile of tumor specimen TARGET-40-PANZHX-01A (aliquot TARGET-40-PANZHX-01A-01D) from TARGET case TARGET-40-PANZHX, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 14.0 years (5,127 days).
Specimen TARGET-40-PANZHX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d03fbd7-f065-4ed3-a992-8e1871508ddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANZHX-10A (Blood Derived Normal), aliquot TARGET-40-PANZHX-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe00ac90-86cd-4c99-8e77-ff5bd37ab647

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKEF1 | c.1600G>A p.A534T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs1463614581; called by muse, mutect2
- BRCA2 | c.3854A>G p.E1285G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs747103920; ClinVar: uncertain significance; called by muse, varscan2
- IGKV3-15 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs1339431431; called by muse, mutect2, varscan2
- PRMT2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.6); catalogued as rs899553433, COSV52457696; called by muse, mutect2, varscan2
- WDR45 | c.958G>A p.V320I (on ENST00000376372 / NM_001029896.2; = p.V321I on NM_007075.3) | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.101); catalogued as rs1254175963; called by muse, varscan2
- COL12A1 | c.8539G>C p.D2847H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF3E | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by mutect2, varscan2
- MYH6 | c.2513T>C p.I838T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF114 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SEC16A | c.2215C>T p.L739F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- WBP11 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF432 | c.1310G>T p.G437V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CADM3 | c.1140C>T p.I380= (on ENST00000368125 / NM_001127173.3; = p.I414= on NM_021189.5) | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV63672821; called by muse, mutect2
- CFAP298-TCP10L | c.627G>A p.G209= | Silent (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- EDARADD | c.508C>A p.R170= (on ENST00000334232 / NM_145861.4; = p.R160= on NM_080738.4) | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as CM138359, COSV62064302, COSV62065263; called by muse, mutect2
- ERICH3 | c.3933C>T p.D1311= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs767197875; called by muse, mutect2, varscan2
- LIX1L | c.970C>T p.L324= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- NOS1 | c.1755C>T p.S585= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs756897335, COSV100500353; called by muse, mutect2, varscan2
- STMN2 | c.168G>T p.L56= | Silent (SNP) | VAF 3/27 reads (11%) | catalogued as COSV55219836; called by muse, mutect2
- ATP2B1 | c.2248-54T>C | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, varscan2
- VSIG4 | c.*6C>T | 3'UTR (SNP) | VAF 3/34 reads (9%) | catalogued as rs960011460; called by muse, mutect2
